Surgical pathology report (de-identified scan), TCGA case TCGA-QG-A5YX, project TCGA-COAD (Colon Adenocarcinoma), tissue source site BLN - Baylor, specimen TCGA-QG-A5YX-01A (Primary Tumor).

[page 1 of 4]
urgical Pathology:

SURGICAL PATHOLOGY

Accession #:

Collected:

PATHOLOGIC DIAGNOSIS

A. COLON, SIGMOID, SIGMOIDECTOMY:

- INVASIVE ADENOCARCINOMA
- TUMOR SITE: SIGMOID COLON
- TUMOR SIZE:
- GREATEST DIMENSION: 7.6 CM
- ADDITIONAL DIMENSIONS: 3.2 CM X 2 CM
- HISTOLOGIC GRADE: LOW-GRADE (WELL TO MODERATELY DIFFERENTIATED)
- MICROSCOPIC TUMOR EXTENSION:
- TUMOR INVADES THROUGH MUSCULARIS PROPRIA INTO THE SUBSEROSAL ADIPOSE TISSUE
- MARGINS:
- PROXIMAL, DISTAL AND RADIAL MARGINS UNINVOLVED BY INVASIVE CARCINOMA
- DISTANCE OF INVASIVE CARCINOMA FROM CLOSEST MARGIN: 2 MM FROM RADIAL MARGIN
- TREATMENT EFFECT: NOT KNOWN
- LYMPHOVASCULAR INVASION: PRESENT
- PERINEURAL INVASION: NOT IDENTIFIED
- TUMOR DEPOSITS: NOT IDENTIFIED
- LYMPH NODES: NO METASTATIC CARCINOMA IDENTIFIED IN THIRTEEN LYMPH NODES (0/13) (SEE COMMENT)

B. COLON, DESCENDING, NEW PROXIMAL MARGIN, EXCISION:

- UNREMARKABLE COLONIC MUCOSA AND WALL

C. COLON, DESCENDING, PROXIMAL DONUT, EXCISION:

- UNREMARKABLE COLONIC MUCOSA AND WALL

D. RECTUM, DISTAL DONUT, EXCISION:

- UNREMARKABLE COLONIC MUCOSA AND WALL

ICD-O-3

Adenocarcinoma NOS 8140/3

Site Sigmoid colon C18.9

Q10 4/16/13

[page 2 of 4]
E. SPLEEN, SPLENECTOMY:

- BENIGN PARENCHYMA WITH SUBCAPSULAR HEMORRHAGE

PATHOLOGIC STAGING:

Primary Tumor (pT): pT3

Regional Lymph Nodes (pN): pN0

Distant Metastasis (pM): Not applicable

Pathologic Staging: IIA

Staff Pathologist

Comment

Please see surgical report for complete information regarding microsatellite instability testing, which revealed positive staining by tumor for MSH-2, MSH-6, PMS-2, and MLH-1.

The specimen was examined twice in order to identify a total of thirteen lymph nodes (0/13).

Intraoperative Consultation

Intraoperative Gross Consultation Diagnosis

Part A: Sigmoid colon, sigmoid colectomy:

- Tumor grossly located 2.5 cm from proximal margin
- Verbally reported to

Staff Pathologist

Pathology Resident

Pertinent Clinical Information

Pertinent History/Operative Findings: -year-old with history of sigmoid colon cancer. Tattooed sigmoid mass resected with appropriate margins (greater than 3 cm).

Gross Description

Specimen Material: A- Sigmoid colectomy - stitch distal, B- Descending colon - new proximal margin- long silk suture, C- Proximal donut from descending colon, D- Distal donut from rectum, E- Spleen.

The case is received in five parts, each labeled with the patient's name medical record number and given accession number
, and it is accompanied by a requisition form labeled with the same

[page 3 of 4]
name and accession number.

Part A: Received fresh labeled with the patient's name and "SIGMOID COLECTOMY GROSS MARGIN, STITCH DISTAL" is a 26.0 cm long section of sigmoid colon with an average diameter of 3-4cm. The specimen is received stapled at both ends, and there is a stitch at the distal end, as oriented by the surgeon. The radial margin is inked black. The serosal surface is smooth, yellow, with abundant attached peri-sigmoidal fat. The mucosa is tan with normal plications. A 7.6 x 3.2 cm tan-brown fungating mass is present within the lumen, located 2.5 cm from the nearest margin (proximal margin). The mass extends grossly to the serosa with a maximal depth of 2.0 cm, and is solid, tan, with a central clear mucinoid area. Multiple bright yellow oval lymph nodes ranging from 0.2 to 1.0 cm are identified.

Representative sections are submitted as follows:

- A1: four presumptive lymph nodes
- A2: representative section of proximal margin, en face
- A3: representative section of distal margin, en face
- A4: uninvolved colon
- A5-A7: tumor to greatest depth of invasion
- A8-A11: tumor
- A12: five lymph nodes
- A13: five lymph nodes
- A14: five lymph nodes
- A15: two lymph nodes
- A16: four lymph nodes
- A17: two lymph nodes
- A18: tumor

Part B: Received in formalin labeled with the patient's name and "NEW PROXIMAL MARGIN" is a 1.6 cm long and 1.7 cm diameter piece of tan-pink colon. The long stitch identifies the new proximal margin, as oriented by the surgeon, which is received stapled. The serosa is smooth and pink. The mucosa is tan, smooth and normally plicated.

Cassette Summary:

- B1: margin, en face

Part C: Received in formalin labeled "PROXIMAL DONUT FROM DESCENDING COLON" is a 2 x 2 x 0.5 cm tan-pink mucosal donut with attached blue Prolene suture. The mucosal surface is tan and edematous with petechial hemorrhage identified. No discrete masses are found. A representative section is submitted in C.

Part D: Received in formalin labeled "DISTAL DONUT FROM RECTUM" is a 1 x 1

[page 4 of 4]
x 0.8 cm tan-pink, mucosal donut. The mucosal surface is edematous and displays petechial hemorrhage. No discrete masses are identified. A representative section is submitted in D.

Part E: Received in formalin labeled "SPLEEN" is a 78 gram, 9.0 x 6.0 x 2.8 cm tan-pink to pink-purple spleen with little attached hilar fat. The capsular surface displays leathery granularity and is gray-maroon, with a 3.2 x 2.2 cm focus of subcapsular, dark red-brown blood. The cut surface displays homogenous tan-red parenchyma without lesions. The cut surface of the subcapsular lesion shows an organizing subcapsular hematoma. No other discrete lesions are identified.

Representative sections are submitted in cassettes:

E1: subcapsular hematoma

E2: parenchyma

Pathology Assistant

Microscopic Description

A-E: Performed.

The staff pathologist listed below reviewed this case.

Pathology Resident

Electronically Signed Out

Staff Pathologist

Histology Discrepancy		☒

Source: NCI Genomic Data Commons file c470409d-b83a-44f8-80d6-6a97237dd6f8 (TCGA-QG-A5YX.D948972B-8F4F-4C2A-9072-7D4A7E1B58DE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).